Somatic mutation profile of tumor specimen MP2PRT-PAPXIW-TMP1-A (aliquot MP2PRT-PAPXIW-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPXIW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,576 days).
Specimen MP2PRT-PAPXIW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8d08d17-d215-49ea-af56-747483b87c02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXIW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXIW-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ed59459-b75e-4476-94f7-d09de4a8bd56

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, In Frame Ins 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPTBN2 | c.4943C>T p.A1648V | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs145844240; called by muse, mutect2, varscan2
- ANKRD35 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- HMGCLL1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SEC16A | c.3743G>T p.G1248V | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV20-1 | c.329_330insCCC p.A110_R111insP | In Frame Ins (INS) | VAF 58/96 reads (60%) | called by mutect2, varscan2
- TRBV20-1 | c.331_335del p.R111_*112del | Frame Shift Del (DEL) | VAF 57/84 reads (68%) | called by mutect2, pindel*, varscan2
- UBA2 | c.1523_1524insGGGG p.F509Gfs*5 | Frame Shift Ins (INS) | VAF 67/208 reads (32%) | called by mutect2, pindel, varscan2
- UNC79 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- BRINP1 | c.1524C>T p.N508= | Silent (SNP) | VAF 32/450 reads (7%) | catalogued as rs1451364922, COSV56317361; called by muse, mutect2
- DHX15 | c.411C>A p.L137= | Silent (SNP) | VAF 30/381 reads (8%) | called by muse, mutect2
- TMPRSS4 | c.795G>A p.L265= | Silent (SNP) | VAF 16/421 reads (4%) | catalogued as rs1270569831; called by muse, mutect2
